Somatic mutation profile of tumor specimen TCGA-X7-A8M1-01A (aliquot TCGA-X7-A8M1-01A-11D-A423-09) from TCGA case TCGA-X7-A8M1, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type AB, NOS; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 51.5 years (18,826 days).
Specimen TCGA-X7-A8M1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7e422c0-a65e-4afe-996f-2fb9f27d00fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X7-A8M1-10A (Blood Derived Normal), aliquot TCGA-X7-A8M1-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec18ba22-9f45-48cf-8c22-76cac1f94aa5

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 7, Silent 5, Nonsense Mutation 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 66/446 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- IGHD | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs376901676, COSV101162941, COSV66654942; called by muse, mutect2, varscan2
- MYO1E | c.423C>T p.H141= | Splice Region (SNP) | VAF 11/57 reads (19%) | catalogued as rs780146456; called by muse, mutect2, varscan2
- GMIP | c.2092G>A p.A698T | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2
- INTS6L | c.2033A>G p.H678R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NLRC5 | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2
- PCLO | c.10922T>A p.V3641E | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SMG6 | c.2074C>A p.L692M | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- SWAP70 | c.1144G>T p.E382* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- ZNF574 | c.1195_1215del p.T399_K405del | In Frame Del (DEL) | VAF 8/35 reads (23%) | called by mutect2, pindel
- ATP12A | c.1788C>A p.S596= | Silent (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- DYSF | c.402G>A p.P134= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs973059586, COSV50514950; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HMCN1 | c.8853T>C p.S2951= | Silent (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2, varscan2
- MYH13 | c.1572G>A p.E524= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as COSV52829474; called by muse, mutect2, varscan2
- RWDD4 | c.51T>A p.I17= | Silent (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
